Somatic mutation profile of tumor specimen TCGA-CJ-4918-01A (aliquot TCGA-CJ-4918-01A-01D-1429-08) from TCGA case TCGA-CJ-4918, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Clear cell adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage IV; Tumor grade: G4; Age at diagnosis: 64.0 years (23,379 days).
Specimen TCGA-CJ-4918-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 421e59c7-7561-4d54-be01-0d5d891048d0.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CJ-4918-11A (Solid Tissue Normal), aliquot TCGA-CJ-4918-11A-01D-1429-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/206c4ca1-9f66-4772-83ff-b8bd44e1d7e2

The open-access MAF lists 76 somatic variants for this specimen: 63 protein-altering or splice-affecting, 12 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 47, Silent 12, Frame Shift Del 8, Splice Site 3, In Frame Del 2, Nonsense Mutation 2, Splice Region 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EHMT1 | c.2712+1G>A p.X904_splice | Splice Site (SNP) | VAF 10/89 reads (11%) | catalogued as rs1057518849, CS136928, COSV71777240; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ZBTB7A | c.1272G>T p.K424N | Missense Mutation (SNP) | VAF 8/58 reads (14%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59326106; called by muse, mutect2, varscan2
- AC008397.2 | c.761C>T p.S254F | Missense Mutation (SNP) | VAF 62/343 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV53204498; called by muse, mutect2, varscan2
- AFF3 | c.146G>C p.S49T | Missense Mutation (SNP) | VAF 6/51 reads (12%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.724); catalogued as COSV57838924; called by muse, mutect2, varscan2
- ALMS1 | c.9635C>A p.T3212N | Missense Mutation (SNP) | VAF 30/192 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100042296, COSV52501823; called by muse, mutect2, varscan2
- ANK3 | c.3068G>C p.R1023P (on ENST00000280772 / NM_001320874.2; = p.R157P on NM_001149.3) | Missense Mutation (SNP) | VAF 29/177 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55042822; called by muse, mutect2, varscan2
- ANXA3 | c.718C>A p.L240M | Missense Mutation (SNP) | VAF 19/153 reads (12%) | SIFT tolerated (0.65); PolyPhen probably damaging (1); catalogued as COSV53712973; called by muse, mutect2, varscan2
- ATP8B1 | c.994A>G p.K332E | Missense Mutation (SNP) | VAF 22/94 reads (23%) | SIFT tolerated (0.05); PolyPhen benign (0.436); catalogued as COSV52172775; called by muse, mutect2, varscan2
- BCAR3 | c.360C>T p.F120= | Splice Region (SNP) | VAF 20/147 reads (14%) | catalogued as COSV53071580; called by muse, mutect2, varscan2
- CDK5RAP2 | c.2107-1G>A p.X703_splice | Splice Site (SNP) | VAF 10/91 reads (11%) | catalogued as COSV62571832; called by muse, mutect2, varscan2
- CLTC | c.3224T>C p.F1075S | Missense Mutation (SNP) | VAF 34/212 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as COSV52244554, COSV52251665; called by muse, mutect2, varscan2
- COPS2 | c.500A>G p.K167R | Missense Mutation (SNP) | VAF 17/105 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV54644060; called by muse, mutect2, varscan2
- CSK | c.413T>A p.L138H | Missense Mutation (SNP) | VAF 8/82 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV54972435; called by muse, mutect2
- DNAH8 | c.9989A>T p.D3330V | Missense Mutation (SNP) | VAF 7/58 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV59422633; called by muse, mutect2, varscan2
- ECEL1 | c.952C>G p.Q318E | Missense Mutation (SNP) | VAF 26/125 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.321); catalogued as COSV58811101; called by muse, mutect2, varscan2
- EML4 | c.86C>A p.S29* | Nonsense Mutation (SNP) | VAF 20/135 reads (15%) | catalogued as COSV59292241; called by muse, mutect2, varscan2
- EPHB4 | c.827T>G p.F276C | Missense Mutation (SNP) | VAF 28/267 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV62267801; called by muse, mutect2, varscan2
- FMN2 | c.2119G>T p.G707C | Missense Mutation (SNP) | VAF 16/124 reads (13%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.007); catalogued as COSV60415502, COSV60420397; called by muse, mutect2, varscan2
- GJB6 | c.605G>T p.C202F | Missense Mutation (SNP) | VAF 10/112 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1364245978, COSV53831732; called by muse, mutect2
- GRIA1 | c.116A>G p.H39R | Missense Mutation (SNP) | VAF 33/252 reads (13%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.455); catalogued as COSV53587404; called by muse, mutect2, varscan2
- GRM5 | c.1867G>T p.A623S | Missense Mutation (SNP) | VAF 14/100 reads (14%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.793); catalogued as COSV59588683; called by muse, mutect2, varscan2
- HIF1A | c.2094-1G>C p.X698_splice | Splice Site (SNP) | VAF 11/90 reads (12%) | catalogued as COSV60188057; called by muse, varscan2
- HUS1 | c.575del p.L192* | Frame Shift Del (DEL) | VAF 13/95 reads (14%) | catalogued as COSV99346388; called by mutect2, pindel, varscan2
- JAG1 | c.1875C>A p.Y625* | Nonsense Mutation (SNP) | VAF 30/264 reads (11%) | catalogued as CM993753, COSV54752988; called by muse, mutect2, varscan2
- JAK2 | c.158A>C p.D53A | Missense Mutation (SNP) | VAF 57/315 reads (18%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as COSV67571722; called by muse, mutect2, varscan2
- KALRN | c.4858G>A p.D1620N | Missense Mutation (SNP) | VAF 18/169 reads (11%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); catalogued as rs780940425, COSV53752017; called by muse, varscan2
- KCNN2 | c.412G>T p.A138S (on ENST00000264773; = p.A350S on NM_021614.4) | Missense Mutation (SNP) | VAF 18/96 reads (19%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.999); catalogued as COSV53282390; called by muse, mutect2, varscan2
- LACC1 | c.1006C>A p.P336T | Missense Mutation (SNP) | VAF 50/301 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV57828569; called by muse, mutect2, varscan2
- LRRIQ3 | c.1312G>A p.E438K | Missense Mutation (SNP) | VAF 56/359 reads (16%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs267598713, COSV63040767; called by muse, mutect2, varscan2
- MIA2 | c.1279G>A p.E427K | Missense Mutation (SNP) | VAF 22/143 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.068); catalogued as rs774358057, COSV54488097; called by muse, mutect2, varscan2
- MRPL30 | c.445T>G p.W149G | Missense Mutation (SNP) | VAF 37/263 reads (14%) | SIFT tolerated (0.11); PolyPhen benign (0.024); catalogued as COSV57666411; called by muse, mutect2, varscan2
- NUAK2 | c.1811G>A p.C604Y | Missense Mutation (SNP) | VAF 22/131 reads (17%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.491); catalogued as COSV65680772; called by muse, mutect2, varscan2
- NUP210L | c.3209G>A p.R1070K | Missense Mutation (SNP) | VAF 35/166 reads (21%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as rs1355304010, COSV55140943, COSV55146962; called by muse, mutect2, varscan2
- OGDH | c.1472C>A p.A491D | Missense Mutation (SNP) | VAF 9/50 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV56045136; called by muse, mutect2, varscan2
- POLE | c.3409C>A p.L1137M | Missense Mutation (SNP) | VAF 21/98 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV57673490; called by muse, mutect2, varscan2
- PTPRU | c.2920C>G p.R974G | Missense Mutation (SNP) | VAF 11/103 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV60521410; called by muse, mutect2, varscan2
- RAPGEF2 | c.3426T>A p.D1142E | Missense Mutation (SNP) | VAF 35/224 reads (16%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.997); catalogued as COSV52424514; called by muse, mutect2, varscan2
- RDH5 | c.55A>G p.R19G | Missense Mutation (SNP) | VAF 32/190 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as CM116266, COSV57675908; called by muse, varscan2
- SGO2 | c.2426G>T p.R809I | Missense Mutation (SNP) | VAF 26/180 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); catalogued as COSV63413741; called by muse, mutect2, varscan2
- SLC12A2 | c.2610G>C p.L870F | Missense Mutation (SNP) | VAF 11/126 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.793); catalogued as COSV52467584; called by muse, mutect2
- SLC24A2 | c.1397A>T p.E466V | Missense Mutation (SNP) | VAF 50/280 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.007); catalogued as COSV53856637; called by muse, varscan2
- SLC30A9 | c.1388C>G p.T463S | Missense Mutation (SNP) | VAF 29/148 reads (20%) | SIFT tolerated (0.2); PolyPhen benign (0.173); catalogued as COSV52553778; called by muse, mutect2, varscan2
- SLC38A8 | c.645G>T p.W215C | Missense Mutation (SNP) | VAF 8/87 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV55304201; called by muse, mutect2, varscan2
- SLC8B1 | c.1496T>A p.I499N | Missense Mutation (SNP) | VAF 27/226 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.232); catalogued as COSV52526094; called by muse, mutect2, varscan2
- SLC8B1 | c.642C>A p.F214L | Missense Mutation (SNP) | VAF 63/399 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.02); catalogued as COSV52526104; called by muse, mutect2, varscan2
- STK31 | c.668A>T p.E223V | Missense Mutation (SNP) | VAF 23/167 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.115); catalogued as COSV63453772; called by muse, mutect2, varscan2
- TMPRSS15 | c.1753G>T p.G585C | Missense Mutation (SNP) | VAF 25/186 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53034304; called by muse, mutect2, varscan2
- TNFRSF9 | c.208G>T p.G70C | Missense Mutation (SNP) | VAF 43/373 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1399281402, COSV101097333, COSV66348694; called by muse, mutect2, varscan2
- TRAF5 | c.1495T>A p.F499I | Missense Mutation (SNP) | VAF 18/149 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54820863; called by muse, mutect2, varscan2
- UHRF1BP1 | c.1793_1794del p.E598Afs*29 | Frame Shift Del (DEL) | VAF 22/154 reads (14%) | catalogued as rs1160843851; called by pindel, varscan2
- WDFY3 | c.7103A>T p.K2368M | Missense Mutation (SNP) | VAF 65/364 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV55692536; called by muse, mutect2, varscan2
- WDPCP | c.1277T>A p.L426Q | Missense Mutation (SNP) | VAF 50/231 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV55412242; called by muse, mutect2, varscan2
- ZC3H13 | c.830G>A p.G277E | Missense Mutation (SNP) | VAF 54/327 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.541); catalogued as COSV54447131; called by muse, mutect2, varscan2
- ZNF211 | c.1313C>G p.S438C (on ENST00000347302 / NM_198855.4; = p.S451C on NM_006385.5) | Missense Mutation (SNP) | VAF 28/170 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0.035); catalogued as COSV53739568, COSV53745716; called by muse, mutect2, varscan2
- ZSCAN1 | c.455A>C p.E152A | Missense Mutation (SNP) | VAF 39/182 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.029); catalogued as COSV56601286, COSV56606850; called by muse, mutect2, varscan2
- ASPG | c.1273del p.S425Vfs*36 | Frame Shift Del (DEL) | VAF 6/58 reads (10%) | called by mutect2, pindel
- CD28 | c.339_341del p.K113_I114delinsN | In Frame Del (DEL) | VAF 20/140 reads (14%) | called by mutect2, pindel, varscan2
- FOXJ3 | c.919del p.S307Hfs*7 | Frame Shift Del (DEL) | VAF 53/415 reads (13%) | called by mutect2, pindel, varscan2
- ITSN2 | c.4019del p.G1340Efs*9 | Frame Shift Del (DEL) | VAF 39/253 reads (15%) | called by mutect2, pindel, varscan2
- KRT12 | c.303del p.F101Lfs*10 | Frame Shift Del (DEL) | VAF 54/436 reads (12%) | called by mutect2, pindel, varscan2
- OR6K6 | c.78_86del p.Q27_T29del (on ENST00000368144; = p.QLT3_?5 on NM_001005184.1) | In Frame Del (DEL) | VAF 32/252 reads (13%) | called by mutect2, pindel, varscan2
- RABGAP1L | c.2255del p.L752* | Frame Shift Del (DEL) | VAF 21/159 reads (13%) | called by mutect2, pindel, varscan2
- WDR1 | c.902del p.I301Tfs*26 (on ENST00000382452; = p.I161Tfs*26 on NM_005112.5) | Frame Shift Del (DEL) | VAF 7/25 reads (28%) | called by mutect2, pindel, varscan2
- AIPL1 | c.315G>A p.R105= | Silent (SNP) | VAF 31/180 reads (17%) | catalogued as COSV51505800; called by muse, mutect2, varscan2
- AOPEP | c.2178C>T p.P726= (on ENST00000375315 / NM_001193329.1; = p.P627= on NM_032823.5) | Silent (SNP) | VAF 21/160 reads (13%) | catalogued as COSV52985097; called by muse, mutect2, varscan2
- B4GALNT1 | c.1506C>T p.A502= | Silent (SNP) | VAF 28/160 reads (18%) | catalogued as COSV57541063; called by muse, mutect2, varscan2
- BCO2 | c.471T>C p.V157= | Silent (SNP) | VAF 13/70 reads (19%) | catalogued as COSV63062472; called by muse, mutect2, varscan2
- COL15A1 | c.3765T>G p.S1255= | Silent (SNP) | VAF 45/220 reads (20%) | catalogued as COSV66641052; called by muse, mutect2, varscan2
- MTTP | c.1104C>T p.T368= | Silent (SNP) | VAF 43/408 reads (11%) | catalogued as COSV55503583; called by muse, mutect2, varscan2
- MYRF | c.1995C>T p.N665= (on ENST00000278836 / NM_001127392.3; = p.N656= on NM_013279.4) | Silent (SNP) | VAF 17/151 reads (11%) | catalogued as rs778946331, COSV53885520; called by muse, mutect2, varscan2
- PXDC1 | c.610C>T p.L204= | Silent (SNP) | VAF 21/96 reads (22%) | catalogued as rs760245275, COSV66661196; called by muse, mutect2, varscan2
- SLC17A4 | c.1449A>T p.A483= | Silent (SNP) | VAF 64/307 reads (21%) | catalogued as COSV55076976; called by muse, mutect2, varscan2
- SLC8B1 | c.1497C>T p.I499= | Silent (SNP) | VAF 29/234 reads (12%) | catalogued as COSV52526085; called by muse, mutect2, varscan2
- TPR | c.1428C>T p.N476= | Silent (SNP) | VAF 30/212 reads (14%) | catalogued as COSV66599158; called by muse, mutect2, varscan2
- WAPL | c.2046T>A p.A682= | Silent (SNP) | VAF 21/140 reads (15%) | catalogued as COSV53932118; called by muse, mutect2, varscan2
- MIR544A | n.36T>G | RNA (SNP) | VAF 15/72 reads (21%) | called by muse, mutect2, varscan2
